MMRF case MMRF_1638 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2ca3bbd6-7810-40f2-a05f-58252e7a14f0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Dead; Days to death: 808 days (2.2 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.9 years (24,082 days); ISS stage: I; Days to last known disease status: 808 days (2.2 years); Days to last follow up: 808 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 15 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 128 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 135 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 184 days; Days to treatment end: 184 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 185 days; Days to treatment end: 185 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 319 days; Days to treatment end: 767 days (2.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 683 days (1.9 years); Days to treatment end: 767 days (2.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 808.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 1): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1010 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 0.93 g/L; Beta 2 Microglobulin 2.56 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 13 ×10⁹/L; Absolute Neutrophil 9 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 100 µmol/L; Blood Urea Nitrogen 6.8 mmol/L; Calcium 2.29 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.5 mmol/L.
- Day 82 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 181 mg/dL; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 9.92 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 87 µmol/L; Blood Urea Nitrogen 5.4 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 5.9 g/dL; Glucose 6.6 mmol/L.
- Day 164 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 88.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Beta 2 Microglobulin 2.25 µg/mL; Hemoglobin 9.73 mmol/L; Leukocytes 67.5 ×10⁹/L; Absolute Neutrophil 60 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 107 µmol/L; Calcium 2.49 mmol/L; Albumin 37 g/L; Glucose 4.5 mmol/L.
- Day 281 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 9.71 g/L; Immunoglobulin A 1.55 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 8 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.1 mmol/L.
- Day 341 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.44 mg/dL; Beta 2 Microglobulin 2.95 µg/mL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 88 µmol/L; Blood Urea Nitrogen 3.9 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 6.3 mmol/L.
- Day 387 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.59 mg/dL; Beta 2 Microglobulin 3.85 µg/mL; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.7 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 152 µmol/L; Blood Urea Nitrogen 6.6 mmol/L; Calcium 1.82 mmol/L; Albumin 29 g/L; Total Protein 5.4 g/dL; Glucose 7.4 mmol/L.
- Day 514: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Beta 2 Microglobulin 4.35 µg/mL.

Other clinical attributes
- Day -16: Weight: 98 kg; Height: 167 cm.

Biospecimens (2 samples)
- Sample MMRF_1638_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1638_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
